Somatic mutation profile of tumor specimen TCGA-CG-4476-01A (aliquot TCGA-CG-4476-01A-01D-1158-08) from TCGA case TCGA-CG-4476, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.8 years (25,506 days).
Specimen TCGA-CG-4476-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01e47148-0a31-4903-ab1c-aeef04acd019.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-4476-10A (Blood Derived Normal), aliquot TCGA-CG-4476-10A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2055a2ac-019e-4368-b05b-1cd1f26821d9

The open-access MAF lists 119 somatic variants for this specimen: 99 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 19, Nonsense Mutation 10, Frame Shift Del 3, Splice Site 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3391C>T p.Q1131* | Nonsense Mutation (SNP) | VAF 47/106 reads (44%) | catalogued as rs878853438, CM014887, COSV57337186; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.376-19_384del p.X126_splice | Splice Site (DEL) | VAF 11/54 reads (20%) | hotspot (GDC flag); called by mutect2, pindel
- ABCC9 | c.3381G>A p.M1127I | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53962382; called by muse, mutect2
- ADA2 | c.916C>T p.R306* (on ENST00000262607; = p.R65* on NM_177405.3) | Nonsense Mutation (SNP) | VAF 35/112 reads (31%) | catalogued as rs774963498, CM145322, COSV52833051; called by muse, mutect2, varscan2
- ADAMTS10 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.532); catalogued as rs371686886, COSV99547136; called by muse, mutect2
- AIMP1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs202139899, COSV63639440; called by muse, mutect2, varscan2
- AMPD2 | c.1717G>A p.V573M | Missense Mutation (SNP) | VAF 35/346 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1377468116, COSV56649998; called by muse, mutect2, varscan2
- ANKDD1A | c.791A>G p.Y264C | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs758796632, COSV60354061; called by muse, mutect2
- ASIC5 | c.526T>C p.Y176H | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV72233064; called by muse, mutect2
- ATG2B | c.2575T>A p.S859T | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.629); catalogued as COSV63424943; called by muse, mutect2, varscan2
- BEST2 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.088); catalogued as COSV50375236; called by muse, mutect2, varscan2
- COL12A1 | c.3774C>G p.D1258E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as rs375043994, COSV59405018; called by muse, mutect2, varscan2
- CTBS | c.1035C>G p.N345K | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55364379; called by muse, mutect2
- DCLK1 | c.1930C>A p.H644N | Missense Mutation (SNP) | VAF 22/317 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV55174392, COSV55204278; called by muse, mutect2
- DNAH3 | c.5754G>A p.M1918I | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV54544230; called by muse, mutect2, varscan2
- DOCK6 | c.5268C>G p.F1756L | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV53920485; called by muse, mutect2, varscan2
- DPYD | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.279); catalogued as rs752020412, COSV64593389, COSV64596751; called by muse, mutect2, varscan2
- DYSF | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs143163327; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- EYA1 | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV58158917; called by muse, mutect2
- FAM126A | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as COSV69472352; called by muse, mutect2
- FAT4 | c.6839T>G p.L2280R | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58696578, COSV58703108; called by muse, mutect2
- FEZF2 | c.716C>G p.P239R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs1408490213, COSV51864252; called by muse, mutect2
- FSCN3 | c.1031A>T p.N344I | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.897); catalogued as COSV56171496; called by muse, mutect2, varscan2
- GORAB | c.761C>G p.T254R | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63028700; called by muse, mutect2
- H2AC14 | c.59C>A p.S20Y | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV60798540; called by muse, mutect2, varscan2
- HCN1 | c.1367C>T p.P456L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV57531691; called by muse, mutect2, varscan2
- HDAC3 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV51838421; called by muse, mutect2
- HEATR5B | c.5312C>T p.P1771L | Missense Mutation (SNP) | VAF 65/280 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV51857568; called by muse, mutect2, varscan2
- HECTD4 | c.13045G>C p.D4349H | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66397780, COSV66400041; called by muse, mutect2, varscan2
- IBTK | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 13/70 reads (19%) | catalogued as rs1373746218, COSV60390806; called by muse, mutect2, varscan2
- IGSF10 | c.6906T>A p.N2302K | Missense Mutation (SNP) | VAF 63/227 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56392870; called by muse, mutect2, varscan2
- IL16 | c.1501C>G p.R501G | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV57261942, COSV57267325; called by muse, mutect2
- IMPDH2 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV58708801; called by muse, mutect2, varscan2
- INSRR | c.1256A>G p.N419S | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV63876468; called by muse, mutect2, varscan2
- KCTD3 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 48/211 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.265); catalogued as rs1282734099, COSV52066344; called by muse, mutect2, varscan2
- KERA | c.908G>T p.C303F | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57131558; called by muse, mutect2, varscan2
- KLHL6 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58065439, COSV58068750; called by muse, mutect2
- KRT78 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs202030816, COSV58852135, COSV58853132; called by muse, mutect2, varscan2
- LRP1B | c.3721G>C p.E1241Q | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV67261554; called by muse, mutect2, varscan2
- MAGI2 | c.3494G>C p.R1165T | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV62689606; called by muse, mutect2, varscan2
- MAP1B | c.5842C>T p.R1948W | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs151255965; called by muse, mutect2, varscan2
- MCM3AP | c.1277T>C p.L426P | Missense Mutation (SNP) | VAF 38/148 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV52444301; called by muse, mutect2, varscan2
- MED17 | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52602774; called by muse, mutect2
- METAP1D | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs1220297601, COSV59931843; called by muse, mutect2, varscan2
- METTL4 | c.1356G>A p.W452* | Nonsense Mutation (SNP) | VAF 46/198 reads (23%) | catalogued as COSV60604580; called by muse, mutect2, varscan2
- MFN2 | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 71/293 reads (24%) | catalogued as COSV52424952; called by muse, mutect2, varscan2
- MIPOL1 | c.427A>C p.K143Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.365); catalogued as COSV59391449; called by muse, mutect2, varscan2
- MTMR11 | c.1225C>T p.R409* (on ENST00000439741 / NM_001145862.2; = p.R337* on NM_181873.3) | Nonsense Mutation (SNP) | VAF 31/150 reads (21%) | catalogued as rs782759787, COSV54964566; called by muse, mutect2, varscan2
- MUC16 | c.41526C>A p.C13842* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV66695691; called by muse, mutect2
- MX2 | c.1254G>T p.K418N | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV58098829; called by muse, mutect2, varscan2
- MYH13 | c.3013G>C p.E1005Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV52831613, COSV52839362; called by muse, mutect2, varscan2
- NCAPH | c.1140C>A p.D380E | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV53638046; called by muse, mutect2
- NOMO1 | c.873+1G>T p.X291_splice | Splice Site (SNP) | VAF 52/620 reads (8%) | catalogued as COSV55060835; called by muse, mutect2
- NUP160 | c.3320G>T p.R1107L | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65855594; called by muse, mutect2, varscan2
- NUP35 | c.667A>T p.K223* | Nonsense Mutation (SNP) | VAF 10/62 reads (16%) | catalogued as COSV54559057; called by muse, mutect2, varscan2
- OPCML | c.293A>G p.Y98C | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59443620; called by muse, mutect2, varscan2
- OR5K3 | c.592G>C p.V198L | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV67350535; called by muse, mutect2, varscan2
- PAK1 | c.772+1G>A p.X258_splice | Splice Site (SNP) | VAF 30/265 reads (11%) | catalogued as rs1482673833, COSV53695373, COSV53697384; called by muse, mutect2, varscan2
- PARP12 | c.1231G>A p.A411T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as COSV54936514; called by muse, mutect2, varscan2
- PCDH11X | c.1970C>A p.A657D | Missense Mutation (SNP) | VAF 41/121 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53478686, COSV53500265; called by muse, mutect2, varscan2
- PCDHB2 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV50613920; called by muse, varscan2
- PI16 | c.488G>T p.C163F | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65448558; called by muse, varscan2
- PLXND1 | c.4070G>A p.R1357H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752691422, COSV100140499, COSV60718169; called by muse, mutect2
- PRICKLE1 | c.1580T>G p.L527R | Missense Mutation (SNP) | VAF 30/276 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.255); catalogued as COSV58203470, COSV58209726; called by muse, mutect2, varscan2
- PRKDC | c.2929G>A p.D977N | Missense Mutation (SNP) | VAF 29/225 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV58060794; called by muse, mutect2, varscan2
- PSD4 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV55529289; called by muse, mutect2
- PSPH | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV51913037; called by muse, mutect2, varscan2
- SCN9A | c.4588G>A p.V1530I (on ENST00000303354; = p.V1519I on NM_002977.3) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.298); catalogued as rs577681720, COSV57620781; called by muse, mutect2, varscan2
- SDK1 | c.2443G>A p.G815R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs770835780, COSV67384503; called by muse, mutect2
- SEMA3D | c.864T>A p.N288K | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52401787; called by muse, mutect2
- SEMA4F | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs778626481, COSV60284918; called by muse, mutect2, varscan2
- SLC13A3 | c.518G>T p.S173I | Missense Mutation (SNP) | VAF 168/635 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as COSV51715184; called by muse, mutect2, varscan2
- SLC13A5 | c.472C>A p.Q158K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV53424664; called by muse, mutect2, varscan2
- SLC22A23 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as rs768202996, COSV66674781; called by muse, mutect2, varscan2
- SLC25A6 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 30/243 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV67317939; called by muse, mutect2, varscan2
- SLC5A11 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748302446, COSV61743028; called by muse, mutect2, varscan2
- SLITRK1 | c.1022G>C p.C341S | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65677114; called by muse, mutect2, varscan2
- SLITRK5 | c.2800G>T p.E934* | Nonsense Mutation (SNP) | VAF 60/338 reads (18%) | catalogued as COSV61525382, COSV61527089; called by muse, mutect2, varscan2
- SMAD9 | c.476A>G p.K159R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV63206071; called by muse, mutect2, varscan2
- SPR | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 43/255 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.273); catalogued as COSV52298384; called by muse, mutect2, varscan2
- STAB2 | c.4787G>A p.R1596H | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as rs140998727; called by muse, mutect2, varscan2
- SVIL | c.5208T>A p.Y1736* (on ENST00000355867 / NM_021738.3; = p.Y1310* on NM_003174.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/314 reads (8%) | catalogued as COSV63447075; called by muse, mutect2
- TBX18 | c.1369T>A p.Y457N | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); catalogued as COSV63737819; called by muse, mutect2, varscan2
- THBS4 | c.2695T>C p.Y899H | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63470564; called by muse, mutect2, varscan2
- THSD7B | c.3500G>A p.C1167Y (on ENST00000272643; = p.C1165Y on NM_001316349.2) | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55652477, COSV55726331; called by muse, mutect2, varscan2
- TIAM1 | c.4613G>A p.R1538K | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1227984960, COSV54569125; called by muse, mutect2, varscan2
- TLN1 | c.3818G>A p.R1273Q | Missense Mutation (SNP) | VAF 78/269 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as rs747462166, COSV59210811; called by muse, mutect2, varscan2
- TNR | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV54907324; called by muse, mutect2, varscan2
- TTC21B | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV54633992; called by muse, mutect2, varscan2
- TUBA3C | c.452C>G p.S151C | Missense Mutation (SNP) | VAF 41/208 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.974); catalogued as COSV67139838; called by muse, mutect2, varscan2
- USP54 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as rs781024227, COSV60446358; called by muse, mutect2
- WFS1 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV56991058; called by muse, mutect2, varscan2
- BIRC6 | c.11253_11256del p.T3752Lfs*28 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | called by pindel, varscan2
- FAAP100 | c.1127_1145del p.T376Sfs*18 | Frame Shift Del (DEL) | VAF 43/227 reads (19%) | called by mutect2, pindel, varscan2
- FOXD4L5 | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by mutect2, varscan2
- GDF2 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- HEATR5A | c.3713del p.N1238Tfs*15 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- INTS8 | c.1410A>T p.K470N | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.12); called by muse, mutect2
- TRAV13-2 | c.120T>G p.I40M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- AASDH | c.3003C>A p.I1001= | Silent (SNP) | VAF 14/102 reads (14%) | catalogued as COSV52709515; called by muse, mutect2, varscan2
- BANK1 | c.396A>G p.Q132= | Silent (SNP) | VAF 6/120 reads (5%) | catalogued as rs1172714761, COSV59848347; called by muse, mutect2
- CRB1 | c.2157T>C p.D719= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV66332713; called by muse, mutect2
- EBAG9 | c.597G>T p.R199= | Silent (SNP) | VAF 14/132 reads (11%) | catalogued as COSV61753561, COSV61753748; called by muse, mutect2, varscan2
- FGF10 | c.312G>A p.E104= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV52938552; called by muse, mutect2, varscan2
- FZD4 | c.756G>A p.E252= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1391934477, COSV72294646; called by muse, mutect2, varscan2
- GPR173 | c.222C>T p.V74= | Silent (SNP) | VAF 31/115 reads (27%) | catalogued as COSV60237724; called by muse, mutect2, varscan2
- KCNU1 | c.1008C>T p.V336= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV67753996, COSV67757332; called by muse, mutect2
- MPP2 | c.534G>A p.T178= (on ENST00000461854 / NM_001278372.2; = p.T154= on NM_005374.5) | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs755411782, COSV52239206; called by muse, mutect2, varscan2
- MS4A14 | c.1572C>T p.G524= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as COSV55737317; called by muse, mutect2, varscan2
- NRXN1 | c.480G>A p.P160= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs771181102, COSV68003367; called by muse, mutect2
- PDZRN4 | c.945T>A p.P315= (on ENST00000402685 / NM_001164595.2; = p.P57= on NM_013377.4) | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV100115443, COSV54213555; called by muse, mutect2, varscan2
- PPM1F | c.567G>A p.V189= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV54286220; called by muse, mutect2
- PTPN21 | c.2109C>T p.D703= | Silent (SNP) | VAF 15/146 reads (10%) | catalogued as COSV60851193; called by muse, mutect2, varscan2
- SART1 | c.1683C>T p.R561= | Silent (SNP) | VAF 17/82 reads (21%) | catalogued as COSV56713228; called by muse, mutect2, varscan2
- SCPEP1 | c.210G>T p.L70= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV51855315; called by muse, mutect2, varscan2
- SLITRK5 | c.1479C>T p.I493= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs777152769, COSV61522799; called by muse, mutect2
- TTN | c.100869A>G p.V33623= (on ENST00000591111; = p.V26199= on NM_003319.4) | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV60275132; called by muse, mutect2
- ZNF777 | c.1017C>T p.R339= | Silent (SNP) | VAF 36/170 reads (21%) | catalogued as rs373973043; called by muse, mutect2, varscan2
- RBFOX1 | c.28-185137G>A | Intron (SNP) | VAF 26/271 reads (10%) | catalogued as rs771567004, COSV60946776, COSV60951877; called by muse, mutect2, varscan2
